Surgical pathology report (de-identified scan), TCGA case TCGA-D8-A1JE, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D8-A1JE-01A (Primary Tumor).

[page 1 of 2]
1CD-0-3

Carcinoma, infiltrating ductal, nos 850
Site breast, nos C50.9 3/11/11

page 1 / 2

Department of Cancer Pathology

copy No.

Date:

Examination: Histopathological examination

Internal invoice No.

Cost of diagnostic procedure

Examination No.:

Patient: XXX

PESEL: XXX

Age:

Gender: F

Material: Multiple organ resection – the left breast and axillary tissue

Unit in charge:

Physician in charge:

Material collected on:

Material received on:

Expected time of examination: up to 8 working days

Clinical diagnosis: Cancer of the left breast.

Examination performed on

Results of immunohistochemical examination:

Estrogen receptors found in over 75% of neoplastic cell nuclei.

Progesterone receptors found in over 75% of neoplastic cell nuclei.

HER2 protein stained with HercepTest™ by DAKO.

Negative reaction in invasive cancerous cells (Score = 1+)

Compliance validated by:

Examination performed on:

Macroscopic description:

Left breast sized 19 x 20 x 5 cm removed along with axillary tissues sized 12 x 6 x 2 cm and a 16 x 11 cm skin flap. Weight 800 g. Tumour sized 1.5 x 1.5 x 1.5 cm on the border of upper quadrants, 6.5 cm from the upper boundary, 0.7 cm from the base and 0.1 cm from the skin.

Microscopic description:

Carcinoma ductale invasivum - NHG2 (2 + 2 +3/15 mitoses/10 HPF, visual area diameter 0.55 mm).

Glandular, outside the tumour, tissue showing lesions of the type mastopathia fibrosa et cystica, hyperplasia ductalis simplex (UDH).

AXILLARY LYMPH NODES

Metastases carcinomatosae in lymphonodis No III/X.

Infiltratio capsulae lymphonodorum.

Dual, Synchronous Primary Nodes		
Case Mismatch		

[page 2 of 2]
Histopathological diagnosis:

Carcinoma ductale invasivum mammae sinistrae. Invasive ductal carcinoma of the left breast.

Metastases carcinomatosae in lymphonodis axillae No. III/X. Cancer metastases in axillary lymph nodes No III/X.

(NHG2, pT1c, pN1a).

Compliance validated by:

Source: NCI Genomic Data Commons file fa428a4f-4a78-46a5-b8c4-89e6b3e19a58 (TCGA-D8-A1JE.746C603E-FB1F-40D7-BEAF-20ACE27D6C21.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).